Somatic mutation profile of tumor specimen TCGA-AR-A24S-01A (aliquot TCGA-AR-A24S-01A-11D-A167-09) from TCGA case TCGA-AR-A24S, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.8 years (22,587 days).
Specimen TCGA-AR-A24S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4c84692-0bf4-43e8-b7b4-d5242bc24fb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A24S-10A (Blood Derived Normal), aliquot TCGA-AR-A24S-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9a51206-4561-4cb1-bb56-2b1c009c1a5d

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 29, Silent 12, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.842A>T p.D281V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs587781525, CM004343, CM056068, CM114008, COSV52694391, COSV52729448, COSV52815868; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C14orf93 | c.853T>C p.S285P | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.775); catalogued as COSV100136800; called by muse, mutect2, varscan2
- CBL | c.293T>C p.I98T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV50630825; called by muse, mutect2, varscan2
- CHST2 | c.767A>G p.K256R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.949); catalogued as COSV100536106; called by muse, mutect2
- EPDR1 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs369217258; called by muse, mutect2
- GRM3 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); catalogued as COSV100862887; called by muse, mutect2
- H2AC8 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99773369; called by muse, mutect2, varscan2
- IL3RA | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.998); catalogued as COSV58431158; called by muse, mutect2, varscan2
- IL4R | c.2462A>G p.Y821C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV50142677; called by muse, mutect2, varscan2
- KIAA1109 | c.8876T>A p.V2959D | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.229); catalogued as COSV52671947; called by muse, mutect2, varscan2
- KIAA1109 | c.13659G>C p.K4553N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV52671968; called by muse, mutect2, varscan2
- KIF4A | c.3472G>A p.V1158I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as rs1477625710, COSV65532660; called by muse, mutect2, varscan2
- KMT2C | c.2068G>T p.E690* | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | catalogued as COSV51436763; called by muse, mutect2, varscan2
- MASP1 | c.1160C>G p.T387S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV51459734; called by muse, mutect2, varscan2
- MROH7 | c.3215G>A p.R1072Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778801607, COSV59871655; called by muse, mutect2, varscan2
- MTMR8 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs754619463, COSV100878165, COSV66393759, COSV66396307; called by muse, mutect2, varscan2
- MUC16 | c.14016G>C p.M4672I | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs1315432382, COSV67464220; called by muse, mutect2, varscan2
- PDC | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs757024258, COSV60854215; called by muse, mutect2, varscan2
- PDE8B | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as rs774186250, COSV53741681; called by muse, mutect2, varscan2
- PELI2 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1044129146, COSV50711116; called by muse, mutect2, varscan2
- PNPT1 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs757766273, COSV53177231; called by muse, mutect2, varscan2
- RALB | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55602390; called by muse, mutect2, varscan2
- RELN | c.4790G>A p.G1597E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59000589; called by muse, mutect2, varscan2
- SMARCA5 | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV99304154; called by muse, mutect2
- TYR | c.711C>A p.D237E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54474932; called by muse, varscan2
- UBR2 | c.78+1G>T p.X26_splice | Splice Site (SNP) | VAF 3/34 reads (9%) | catalogued as rs1007420092, COSV100868686, COSV65768997; called by muse, mutect2
- UPRT | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.623); catalogued as COSV64920187; called by muse, mutect2, varscan2
- WDR46 | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65842260; called by muse, mutect2, varscan2
- ZNF648 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV60570840; called by muse, mutect2, varscan2
- ZNF699 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.552); catalogued as COSV58025568; called by muse, mutect2, varscan2
- NDUFA4 | c.52dup p.L18Pfs*32 | Frame Shift Ins (INS) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- RIMKLB | c.918_925del p.L307Wfs*18 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- SYTL1 | c.1359_1377del p.D454Sfs*? (on ENST00000543823; = p.D442Sfs*? on NM_032872.3) | Frame Shift Del (DEL) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- TTC21B | c.2199_2211+8del p.X733_splice | Splice Site (DEL) | VAF 17/56 reads (30%) | called by mutect2, pindel*, varscan2*
- AHNAK2 | c.4812C>T p.D1604= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV60914873; called by muse, mutect2, varscan2
- AKAP9 | c.3552A>G p.L1184= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV62345418; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1201T>C p.L401= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV52353547; called by muse, mutect2, varscan2
- CHL1 | c.3501C>T p.Y1167= (on ENST00000397491 / NM_001253387.1; = p.Y1183= on NM_006614.4) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs529988946, COSV56592868; called by muse, mutect2, varscan2
- COL5A1 | c.4110A>G p.E1370= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV65668746; called by muse, mutect2, varscan2
- FLRT2 | c.465C>T p.F155= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV58141037; called by muse, mutect2, varscan2
- RHBDL3 | c.1062C>T p.G354= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV52186024; called by muse, mutect2, varscan2
- TMEM241 | c.619C>T p.L207= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV67243880; called by muse, mutect2, varscan2
- TSHZ3 | c.1837C>T p.L613= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99552558; called by muse, mutect2
- TTC24 | c.1428G>A p.P476= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs376431462; called by muse, mutect2, varscan2
- UBA1 | c.960C>T p.F320= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1556788530, COSV60112624; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF578 | c.30G>A p.R10= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs1417004313, COSV69736485; called by muse, mutect2, varscan2
